Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACA, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACA-01A (Primary Tumor).

[page 1 of 3]
ICD O-3

Primary tumor

Carcinoma, hepatocellular NOS 817013

Site: Liver C22.0

9/5/14

CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo :

GROSS:

1. Specimen:

Liver: 8.5 x 15.0 x 5.0 cm, 192.0 gm, unfixed

Gallbladder: 9.5 cm in length, 4.5 cm in diameter, and 0.3 cm in thickness, unfixed

2. Tumor location: segment 6

Tumor number: one

Tumor size: 1.8 x 1.8 cm

distant to resection margin: about 0.1 cm

3. Satellite nodule: present

4. Gross type

HCC: vaguely nodular

5. Tumor necrosis: no

6. Other lesion: Thin walled cyst, measuring 1.2 x 0.8 x 0.7 cm

7. Hemorrhage/peliosis: no

8. Portal vein invasion: no

9. Bile duct invasion: no

Gross photo present.

Blocks

T1-3, tumor mass x 3

RM, resection margin x 1

C, cyst x 1

L, non-tumorous liver parenchyme x 1

GB1-2, gallbladder x 2

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation III

The major differentiation II

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Cholangiocarcinoma: no

3. Combined hepatocellular and cholangiocarcinoma: no

[page 2 of 3]
4. Fibrous capsule formation: partial capsule
5. Capsular infiltration: yes
6. Septum formation: no
7. Surgical resection margin invasion: close (<0.1 cm)
8. Serosal invasion: no
9. Portal vein invasion: no
10. Bile duct invasion: no
11. Hepatic vein invasion: no
12. Hepatic artery invasion: no
13. Microvessel invasion: no
14. Intrahepatic metastasis: no
15. Multicentric occurrence: no

Non-tumor liver pathology

1. Chronic hepatitis: yes
- 1-1. Etiology: HBV
- 1-2. Grade, lobular: mild
- 1-3. Grade, portoperiportal: mild
- 1-4. Stage (fibrosis): cirrhosis
- 1-5. Cirrhosis: mixed
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: simple cyst

SPECIAL STAIN: Trichrome highlights fibrotic bands.

NOT reported. Gross:

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma, cirrhosis
T56000, P10, M81703, M49500
Gallbladder, ectomy, cholesterol polyp
T57000, P10, cholesterol polyp

DIAGNOSIS:

Liver, segment 6, segmentectomy:
Hepatocellular carcinoma, well differentiated
Cirrhosis, mixed
Gallbladder, cholecystectomy:

[page 3 of 3]
Cholesterol polyp (autolysis)

NOTE: Recommend to order immunohistochemistry (hepatocyte, CK7, and CK19) for block T2.

Suggestion :

Source: NCI Genomic Data Commons file 8cd52b15-124c-4176-987e-afd790f09373 (TCGA-DD-AACA.6600D758-13D7-4925-BC34-F2A90EE0CFE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).